Somatic mutation profile of tumor specimen TCGA-D8-A1JD-01A (aliquot TCGA-D8-A1JD-01A-11D-A13L-09) from TCGA case TCGA-D8-A1JD, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 41.5 years (15,166 days).
Specimen TCGA-D8-A1JD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 71a93912-7b16-4cb8-b36e-49a1356dbfe9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D8-A1JD-10A (Blood Derived Normal), aliquot TCGA-D8-A1JD-10A-01D-A13O-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d3f62f81-b18c-4e8d-8048-73154875df9d

The open-access MAF lists 101 somatic variants for this specimen: 81 protein-altering or splice-affecting, 16 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 68, Silent 16, Frame Shift Del 6, Nonsense Mutation 4, Intron 2, Splice Site 2, 5'UTR 1, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 19/87 reads (22%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PIK3CA | c.2176G>A p.E726K | Missense Mutation (SNP) | VAF 25/92 reads (27%) | hotspot (GDC flag); SIFT tolerated (0.36); PolyPhen benign (0.396); catalogued as rs867262025, CM126693, COSV55875460; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3012G>A p.M1004I | Missense Mutation (SNP) | VAF 31/116 reads (27%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.047); catalogued as COSV55881019, COSV55891097; called by muse, mutect2, varscan2
- RAD51C | c.61C>G p.P21A | Missense Mutation (SNP) | VAF 6/64 reads (9%) | hotspot (GDC flag); SIFT tolerated (0.32); PolyPhen benign (0.031); catalogued as rs752608224, COSV53611159, COSV53612849, COSV53614404; ClinVar: uncertain significance; called by mutect2, varscan2
- ABCB11 | c.2908C>T p.P970S | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.099); catalogued as rs779096015, COSV55603251; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCG4 | c.1190T>G p.M397R | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.447); catalogued as COSV56646293; called by muse, mutect2, varscan2
- ABL2 | c.730C>T p.L244F (on ENST00000502732 / NM_007314.4; = p.L229F on NM_005158.5) | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs752266744, COSV61022074; called by muse, mutect2, varscan2
- ACSM4 | c.1706G>A p.R569H | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.645); catalogued as rs755058216, COSV68068956; called by muse, mutect2, varscan2
- ACTN4 | c.2425G>A p.A809T | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as COSV53151652; called by muse, varscan2
- AFF3 | c.2763C>A p.S921R | Missense Mutation (SNP) | VAF 21/143 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.119); catalogued as COSV57878822; called by muse, mutect2, varscan2
- ARID1A | c.5841G>T p.Q1947H | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.556); catalogued as COSV61391195; called by muse, mutect2, varscan2
- ARMCX2 | c.121C>G p.P41A | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as COSV100168208; called by muse, mutect2
- BCAR1 | c.2041G>T p.E681* | Nonsense Mutation (SNP) | VAF 10/33 reads (30%) | catalogued as COSV50810572; called by muse, mutect2, varscan2
- CAPG | c.181C>G p.L61V | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.04); catalogued as COSV55709204; called by muse, mutect2, varscan2
- CASP8 | c.1013C>T p.S338F (on ENST00000432109 / NM_033355.3; = p.S355F on NM_001228.4) | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV51852824, COSV51861829; called by muse, mutect2, varscan2
- CDNF | c.428G>C p.R143T | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as COSV101012377; called by muse, varscan2
- CDYL2 | c.739T>G p.C247G | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT tolerated (0.24); PolyPhen benign (0.306); catalogued as COSV73655137; called by muse, mutect2, varscan2
- CILP | c.1138A>G p.S380G | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV56028767; called by muse, mutect2, varscan2
- CNGA2 | c.436G>C p.V146L | Missense Mutation (SNP) | VAF 10/230 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV100323800, COSV104395821; called by muse, mutect2
- COL6A3 | c.3317C>T p.P1106L | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV55090037; called by muse, varscan2
- CYP21A2 | c.521G>A p.C174Y | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.914); catalogued as COSV64481711; called by muse, mutect2, varscan2
- DENND6A | c.362C>G p.S121C | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.49); PolyPhen benign (0.017); catalogued as COSV100231550; called by muse, mutect2
- DEPDC7 | c.493G>A p.D165N (on ENST00000241051 / NM_001077242.2; = p.D156N on NM_139160.2) | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT tolerated (0.42); PolyPhen benign (0.006); catalogued as rs1350896858, COSV99572787; called by muse, mutect2
- EFS | c.1249C>T p.Q417* | Nonsense Mutation (SNP) | VAF 3/33 reads (9%) | catalogued as COSV99391673; called by muse, mutect2
- ELAPOR2 | c.2776T>A p.F926I (on ENST00000450689 / NM_001142749.3; = p.F759I on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as COSV51883517, COSV99789051; called by muse, mutect2, varscan2
- FMR1 | c.690G>T p.M230I | Missense Mutation (SNP) | VAF 21/180 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.519); catalogued as COSV99503398; called by muse, mutect2, varscan2
- FMR1 | c.691G>A p.G231S | Missense Mutation (SNP) | VAF 19/181 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99503474; called by muse, mutect2, varscan2
- GALNT7 | c.548T>A p.I183N | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV53935319; called by muse, mutect2, varscan2
- GIP | c.69G>C p.K23N | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.368); catalogued as rs763582446, COSV62468011; called by muse, mutect2, varscan2
- HGSNAT | c.1141C>G p.L381V | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT tolerated (0.5); PolyPhen benign (0.011); catalogued as COSV52819664; called by muse, mutect2, varscan2
- IGBP1 | c.1012A>G p.M338V | Missense Mutation (SNP) | VAF 18/200 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.317); catalogued as rs145852352, COSV100643008; called by muse, mutect2
- IKBKE | c.1587G>T p.K529N | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.974); catalogued as COSV65626281, COSV65627294; called by muse, mutect2, varscan2
- IL5RA | c.200T>A p.V67E | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56527454; called by muse, mutect2, varscan2
- IQCD | c.1132C>T p.Q378* (on ENST00000416617 / NM_001330452.2; = p.Q276* on NM_138451.3) | Nonsense Mutation (SNP) | VAF 14/77 reads (18%) | catalogued as COSV55324229; called by muse, mutect2, varscan2
- KIF22 | c.1639G>A p.E547K | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs1567362255, COSV50719928; called by muse, mutect2, varscan2
- MAGEE1 | c.1566_1567del p.K523Rfs*8 | Frame Shift Del (DEL) | VAF 6/28 reads (21%) | catalogued as COSV63912604; called by mutect2, pindel, varscan2
- MEIOC | c.785A>C p.E262A | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.074); catalogued as COSV63441789; called by muse, mutect2, varscan2
- NEBL | c.369+1G>T p.X123_splice | Splice Site (SNP) | VAF 12/98 reads (12%) | catalogued as COSV65800303; called by muse, mutect2, varscan2
- NIPAL3 | c.290C>T p.A97V | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs150713534; called by muse, mutect2, varscan2
- NPFFR2 | c.1462C>G p.Q488E | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.036); catalogued as COSV58155642; called by muse, mutect2, varscan2
- OPHN1 | c.1258C>A p.L420M | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100830591; called by muse, mutect2
- OR10H4 | c.385C>A p.H129N | Missense Mutation (SNP) | VAF 41/288 reads (14%) | SIFT tolerated (1); PolyPhen possibly damaging (0.557); catalogued as COSV59063338; called by muse, mutect2, varscan2
- PALM | c.289G>T p.V97L | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV52771576; called by mutect2, varscan2
- PDE3B | c.2116G>C p.D706H | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56392337; called by muse, mutect2, varscan2
- PEX11G | c.103C>A p.L35M | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.92); catalogued as COSV55538072; called by muse, mutect2, varscan2
- PKD1L1 | c.2983G>A p.V995M | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs779114210, COSV56980851, COSV99219908; called by muse, mutect2, varscan2
- PKN2 | c.2479G>C p.E827Q | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV65142372, COSV65144937; called by muse, mutect2, varscan2
- PLEK2 | c.75G>T p.W25C | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99371844; called by muse, mutect2, varscan2
- PLEKHM1 | c.3037T>G p.F1013V | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV69599580; called by muse, mutect2, varscan2
- PMFBP1 | c.2657G>A p.R886Q (on ENST00000537465; = p.R881Q on NM_031293.3) | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as rs769293377, COSV52820915, COSV52830800; called by muse, mutect2, varscan2
- PPP4R3B | c.545G>C p.C182S | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV55410097; called by muse, mutect2, varscan2
- RAP1GDS1 | c.1616A>G p.H539R | Missense Mutation (SNP) | VAF 28/126 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.23); catalogued as COSV52792895; called by muse, mutect2, varscan2
- RSPH4A | c.1886G>T p.W629L | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99994195; called by muse, mutect2, varscan2
- SAMD14 | c.865C>A p.P289T (on ENST00000330175 / NM_001257359.2; = p.P317T on NM_174920.4) | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.334); catalogued as COSV50305412; called by mutect2, varscan2
- SDSL | c.936C>A p.N312K | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.647); catalogued as rs779164441, COSV61885505; called by muse, mutect2, varscan2
- SLC36A2 | c.989G>A p.S330N | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.21); catalogued as COSV58865615; called by muse, mutect2, varscan2
- SLFN13 | c.1860T>G p.F620L | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.189); catalogued as COSV53196115; called by muse, varscan2
- SMYD4 | c.359G>A p.G120D | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.28); catalogued as rs1470404632, COSV59714114; called by muse, mutect2, varscan2
- SPANXN3 | c.302A>G p.D101G | Missense Mutation (SNP) | VAF 18/188 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.041); catalogued as COSV100980821; called by muse, mutect2
- SREBF1 | c.1157G>C p.S386T | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV55420861; called by muse, mutect2, varscan2
- STARD8 | c.727G>C p.D243H | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV52925175, COSV52934156; called by muse, mutect2, varscan2
- SYNE1 | c.11768A>C p.D3923A | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as COSV55131554, COSV99582160; called by muse, mutect2, varscan2
- TAF7L | c.1276A>T p.T426S | Missense Mutation (SNP) | VAF 24/197 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.196); catalogued as COSV61258213; called by muse, mutect2, varscan2
- TAZ | c.452G>A p.R151K | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as COSV50011526; called by muse, mutect2, varscan2
- TCP11L2 | c.860C>A p.A287D | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.12); catalogued as COSV100135445; called by muse, mutect2
- TLN2 | c.6479T>G p.V2160G | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.088); catalogued as COSV60897405; called by mutect2, varscan2
- TMEM170A | c.141G>A p.W47* | Nonsense Mutation (SNP) | VAF 27/50 reads (54%) | catalogued as COSV62923554; called by muse, mutect2, varscan2
- TRAPPC8 | c.3809A>T p.K1270I | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.243); catalogued as COSV51978766; called by muse, mutect2, varscan2
- VAV2 | c.1603A>C p.T535P (on ENST00000371850 / NM_001134398.2; = p.T525P on NM_003371.4) | Missense Mutation (SNP) | VAF 40/382 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV64086233; called by muse, mutect2, varscan2
- WDR93 | c.901C>A p.L301M | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV51536303; called by muse, mutect2, varscan2
- ZFP91 | c.1441G>A p.E481K | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as rs896006462, COSV60162716; called by muse, mutect2, varscan2
- ZNF624 | c.1233T>A p.N411K | Missense Mutation (SNP) | VAF 20/137 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as COSV60941835; called by muse, mutect2, varscan2
- ZNF790 | c.1616G>T p.C539F | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100764856; called by muse, varscan2
- CR2 | c.2946_2956del p.G983Sfs*41 | Frame Shift Del (DEL) | VAF 95/300 reads (32%) | called by mutect2, pindel, varscan2
- CTNND2 | c.2730_2736del p.C910Wfs*26 | Frame Shift Del (DEL) | VAF 11/76 reads (14%) | called by mutect2, pindel, varscan2
- DCHS2 | n.5206_5210del | Splice Region (DEL) | VAF 8/55 reads (15%) | called by mutect2, pindel, varscan2
- GSTT2 | c.685C>A p.P229T | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.829); called by mutect2, varscan2
- HNRNPA1 | c.935_978del p.Y312Sfs*39 (on ENST00000340913 / NM_031157.4; = p.Y260Sfs*39 on NM_002136.4) | Frame Shift Del (DEL) | VAF 9/72 reads (13%) | called by mutect2, pindel
- NCOR1 | c.5882-2del p.X1961_splice | Splice Site (DEL) | VAF 12/46 reads (26%) | called by mutect2, pindel, varscan2
- RC3H1 | c.2721del p.K907Nfs*62 | Frame Shift Del (DEL) | VAF 20/140 reads (14%) | called by mutect2, pindel, varscan2
- SLC37A4 | c.1164del p.K389Sfs*14 | Frame Shift Del (DEL) | VAF 4/29 reads (14%) | called by mutect2, pindel, varscan2
- ARMCX2 | c.123C>A p.P41= | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as COSV100168206, COSV57529566; called by muse, mutect2
- B3GLCT | c.1167C>T p.Y389= | Silent (SNP) | VAF 9/54 reads (17%) | catalogued as COSV58459589; called by muse, mutect2, varscan2
- CDH8 | c.166T>C p.L56= | Silent (SNP) | VAF 7/81 reads (9%) | catalogued as COSV100182639; called by muse, mutect2
- CDK14 | c.876G>C p.V292= (on ENST00000380050 / NM_001287135.2; = p.V274= on NM_012395.3) | Silent (SNP) | VAF 34/81 reads (42%) | catalogued as COSV56056051; called by muse, mutect2, varscan2
- CEMIP | c.1911C>A p.T637= | Silent (SNP) | VAF 14/66 reads (21%) | catalogued as COSV54994202; called by muse, mutect2, varscan2
- CSPG4 | c.3834G>T p.V1278= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as COSV57892361, COSV57902930; called by muse, mutect2, varscan2
- GPRIN3 | c.2121C>A p.I707= | Silent (SNP) | VAF 13/61 reads (21%) | catalogued as COSV60886793; called by muse, mutect2, varscan2
- IGFL1 | c.75C>G p.A25= | Silent (SNP) | VAF 7/105 reads (7%) | catalogued as COSV101473065; called by muse, mutect2
- MLKL | c.75G>A p.K25= | Silent (SNP) | VAF 4/37 reads (11%) | catalogued as COSV100087380; called by mutect2, varscan2
- NOX1 | c.978T>C p.F326= | Silent (SNP) | VAF 7/58 reads (12%) | catalogued as COSV99471635; called by muse, mutect2
- NPHP4 | c.2547C>T p.V849= | Silent (SNP) | VAF 15/40 reads (38%) | catalogued as COSV65398788; called by muse, mutect2, varscan2
- PRAMEF20 | c.1329C>A p.A443= | Silent (SNP) | VAF 27/164 reads (16%) | called by muse, mutect2, varscan2
- RAB4A | c.480G>A p.G160= | Silent (SNP) | VAF 48/172 reads (28%) | catalogued as rs1197716014, COSV64208106; called by muse, mutect2, varscan2
- SLC34A1 | c.789T>A p.A263= | Silent (SNP) | VAF 17/52 reads (33%) | catalogued as COSV60999340; called by muse, mutect2, varscan2
- STAM | c.27C>T p.F9= | Silent (SNP) | VAF 42/108 reads (39%) | catalogued as COSV66326088; called by muse, mutect2, varscan2
- XCR1 | c.273C>T p.Y91= | Silent (SNP) | VAF 43/122 reads (35%) | catalogued as rs1427712887, COSV58571100; called by muse, mutect2, varscan2
- CD200R1 | c.68-16749G>A | Intron (SNP) | VAF 14/84 reads (17%) | catalogued as rs145811094; called by muse, mutect2, varscan2
- OR2M3 | c.-1C>T | 5'UTR (SNP) | VAF 25/220 reads (11%) | catalogued as COSV101513468; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-12696G>A | Intron (SNP) | VAF 19/79 reads (24%) | catalogued as rs202142283; called by muse, mutect2, varscan2
- SSX6P | n.92A>G | RNA (SNP) | VAF 24/204 reads (12%) | called by muse, mutect2, varscan2
